Surgical pathology report (de-identified scan), TCGA case TCGA-BS-A0U8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii, specimen TCGA-BS-A0U8-01A (Primary Tumor).

[page 1 of 3]
100-0-3

adenocarcinoma, endometrioid, NOS 8380/3

Site: Endometrium C54.1 lw 5/1/11

Site Malignancy History		☒
Qualification Primary Notes		☒

Surgical Pathology Report

Patient Name: [REDACTED]

Med. Rec. #: [REDACTED]

DOB: [REDACTED]

Gender: [REDACTED]

Physician(s): [REDACTED]

cc: [REDACTED]

Client: [REDACTED]

Location: [REDACTED]

Accession #: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

History/Clinical Dx: Endometrial cancer

Postoperative Dx: Same, pending pathology examination

Specimen(s) Received:

- A: Anterior bladder flap
- B: Pelvic nodule
- C: Uterine fibroid
- D: Uterus, cervix, tubes and ovaries
- E: Left pelvic lymph node
- F: Left aortic lymph node
- G: Right parametrial tissue
- H: Right pelvic node
- I: Right aortic lymph node
- J: Omentum
- K: Sigmoid

DIAGNOSIS:

- A. Anterior bladder flat: Positive for metastatic adenocarcinoma
- B. Pelvic nodule: Benign epithelial-lined polyp
- C. Uterine fibroid: Leiomyoma
- D. Uterus, cervix, tubes and ovaries: Endometrial adenocarcinoma, endometrioid type
- Tumor Information:
- | | |
|--|--|
| Operative procedure: | Hysterectomy |
| Histologic type: | Adenocarcinoma, endometrioid type |
| Histologic grade(FIGO): | Low grade, FIGO grade 1 |
| Nuclear grade: | 1-2 |
| Tumor size: | 3.5 cm in greatest area |
| Extent of invasion: | Through uterine serosa into parametrial tissue |
| Lympho/vascular invasion: | Present |
| Serosa: | Involved |
| Parametrium: | Involved (extrauterine extension) |
| Cervical involvement: | Free of involvement |
| Adnexa (received separately in container): | Larger ovary positive for metastatic adenocarcinoma
Smaller ovary with microscopic focus of surface |

Regulatory Statement:

The following statement may be applicable to some of the reagents/antibodies used in developing the above report: This test was developed and its performance characteristics determined by [REDACTED] if has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 2 of 3]
Surgical Pathology Report

Involvement by metastatic adenocarcinoma

- E. Left pelvic lymph node: One out of two lymph nodes positive for metastatic adenocarcinoma
- F. Left aortic lymph node: No lymphoid tissue identified
- G. Right parametrial tissue: One lymph node, positive for metastatic adenocarcinoma
- H. Right pelvic node: One lymph node, positive for metastatic adenocarcinoma
- I. Right aortic lymph node: One lymph node, free of tumor
- J. Omentum: Omental tissue, free of metastatic tumor
- K. Sigmoid epiploica: Appendix epiploica

Comments:

has reviewed this case and concurs.

Intraoperative Consultation:

- A. Frozen Section Interpretation: Positive for adenocarcinoma primary

Gross Description

- A. Received fresh labeled "anterior bladder flap tumor" consist of a white-tan portion of soft tissue measuring 1.0 cm in greatest dimension. The entire specimen is submitted for frozen section. The entire frozen section residual is submitted in cassette A.
- B. Received in formalin labeled "infundibulo pelvic nodules" consist of a single tan portion of soft tissue measuring 0.8 cm in greatest dimension. The entire specimen is submitted in cassette B.
- C. Received in formalin labeled "uterine fibroid" consist of a white-tan encapsulated rubbery mass weighing 53.0 gms and measuring 5.0 x 5.0 x 4.5 cm. Serial sectioning reveals a white-tan whorled cut surface. A focal of softened area is seen. No cystic or necrotic areas are identified. Representative sections are submitted in cassette C1-C3.
- D. Received in formalin labeled "cervix uterus right and left ovaries right and left tubes" consist of a uterus and cervix with separate adnexal structures weighing 136.0 gm altogether. The serosal surface of the uterus is tan and smooth superiorly. In the parametrial area is a tan firm mass resembling tumor grossly, attached to the uterine serosa. The uterus is received partially opened revealing an endometrial tumor. The tumor is friable, polypoid, and exophilic and comprises the majority of the endometrial surface. The tumor measures, in area, 3.5 x 3.0 cm. The tumor appears to be invasive, and grossly appears to invade approximately to a depth of 0.9 cm of a 1.5 cm myometrium. The myometrium is serially sectioned to reveal multiple white-tan well-circumscribed masses with a whorled cut surface measuring up to 0.5 cm in greatest dimension. The firm mass within the parametrial tissue is continuous with the myometrium grossly and may represent extension of the tumor through the myometrium. The lower uterine segment appears unremarkable as does the endocervical canal. The exocervical mucosa is tan and smooth.

The adnexal structures are submitted separately in the container. The larger ovary is tan with a cystic appearance measuring 3.0 cm in greatest dimension. Cut section reveals a white-tan friable mass within the ovarian parenchyma measuring 2.0 cm in greatest dimension. The attached fallopian tube measures 3.5 cm in length and up to 0.5 cm in diameter. The smaller ovary is tan and cerebriform measuring 2.0 cm in greatest dimension. Cut section is unremarkable. The attached fallopian tube measures 3.5 cm in length and 0.5 cm in diameter. A paratubal cyst is identified. Representative sections are submitted as follows:

- D1-cervix
- D2-D5-full thickness sections of tumor
- D6 and D7-tumor
- D8-myometrial masses
- D9-lower uterine segment
- D10 and D11-parametrial tissue
- D12-larger ovary and fallopian tubes

[page 3 of 3]
Surgical Pathology Report

D13-smaller ovary and fallopian tubes

- E. Received in formalin labeled "left pelvic lymph node" consist of two yellow-tan portions of soft tissue weighing 5.0 gms and measuring 3.5 x 2.5 x 1.0 cm in greatest dimension. Two lymph nodes are identified. The larger measures 2.3 cm in greatest dimension and on cut section appears to be grossly involved by tumor. Representative sections are submitted as follows: E1-larger lymph node, representative section, E2-smaller lymph node, E3-remaining soft tissue.
- F. Received in formalin labeled "left aortic" consist of a yellow-tan portion of soft tissue measuring 2.5 cm in greatest dimension. The entire specimen is submitted in cassette F.
- G. Received in formalin labeled "right parametrial tissue" consist of a single portion of yellow tan soft tissue containing a possible lymph node measuring 2.5 cm in greatest dimension. The lymph node is bisected and entirely submitted in cassette G.
- H. Received in formalin labeled "right pelvic node" consist of a yellow-tan portion of soft tissue weighing 4.0 gms and measuring 3.0 x 2.3 x 1.5 cm. Within the soft tissue is a large lymph node measuring 3.0 cm in greatest dimension. The node appears grossly involved by tumor on cut section. Representative sections of the node are submitted in cassette H1.
- I. Received in formalin labeled "right aortic" consist of a yellow-tan portion of fibrofatty tissue weighing 3.0 gms and measuring 3.0 cm in greatest dimension. Within the soft tissue is a lymph node measuring 1.7 cm in greatest dimension. The entire specimen is submitted as follows: I1-lymph node, bisected, I2-remainder.
- J. Received in formalin labeled "omentum" consist of three yellow-tan lobulated portions of soft tissue weighing an aggregate 21.0 gms and measuring in aggregate 9.0 x 4.5 x 1.0 cm. Serial sectioning reveals no grossly identifiable lesions. Representative sections are submitted in cassettes J1-J3.
- K. Received in formalin labeled "sigmoid epiploica" consist of a yellow-tan polypoid portion of soft tissue measuring 3.0 cm in greatest dimension and weighing 3.0 gms. Serial sectioning reveals a yellow-tan lobulated cut surface. The entire specimen is submitted in cassettes K1 and K2.

Microscopic Description

A-K. The microscopic findings support the above diagnosis.

[REDACTED]

Source: NCI Genomic Data Commons file e9113cee-7b7d-492b-a598-0c4af70a38f4 (TCGA-BS-A0U8.EAE30BBB-B895-42B9-8AAB-937278A3EBB0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).